Somatic mutation profile of tumor specimen TCGA-FD-A6TK-01A (aliquot TCGA-FD-A6TK-01A-42D-A339-08) from TCGA case TCGA-FD-A6TK, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 60.1 years (21,942 days).
Specimen TCGA-FD-A6TK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1e352bd-4a46-4f6b-8f37-c7d64a0f6881.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A6TK-10A (Blood Derived Normal), aliquot TCGA-FD-A6TK-10A-21D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/325c7d03-9777-4ae3-9c4b-6efbc86bb93d

The open-access MAF lists 127 somatic variants for this specimen: 96 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 27, Nonsense Mutation 10, Frame Shift Del 3, Splice Region 2, RNA 2, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP17A | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58311966, COSV58312170; called by muse, mutect2, varscan2
- ANKRD52 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV57287616; called by muse, mutect2, varscan2
- ANLN | c.1408C>G p.Q470E | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV56074004; called by muse, mutect2
- ANO6 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV57668256; called by muse, mutect2, varscan2
- APOC2 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as rs202190413, CM920061, COSV99377049; called by muse, mutect2, varscan2
- ARHGAP35 | c.1356G>A p.W452* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV101351801; called by muse, mutect2, varscan2
- ARID1A | c.4533del p.R1511Sfs*16 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as COSV61373885; called by mutect2, pindel, varscan2
- ASXL3 | c.5557G>A p.D1853N | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as COSV52480254; called by muse, mutect2, varscan2
- BTBD10 | c.876G>C p.M292I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV53401823; called by muse, mutect2, varscan2
- C9orf131 | c.2673G>C p.K891N | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV56614390; called by muse, mutect2, varscan2
- CACNA1A | c.5203G>A p.E1735K | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV64213017; called by muse, mutect2, varscan2
- CBARP | c.119T>C p.V40A (on ENST00000382477; = p.V46A on NM_152769.3) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV53070930; called by muse, mutect2
- CD109 | c.3814C>T p.R1272* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs200340875, COSV54659231; called by muse, mutect2, varscan2
- CD180 | c.994C>G p.H332D | Missense Mutation (SNP) | VAF 5/107 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.035); catalogued as COSV56519985; called by muse, mutect2
- CELA2A | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62748095; called by muse, mutect2, varscan2
- COL10A1 | c.167G>A p.R56K | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV54572641; called by muse, mutect2
- COL19A1 | c.231C>G p.F77L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.123); catalogued as COSV59589424; called by muse, mutect2, varscan2
- COL22A1 | c.2646G>A p.P882= | Splice Region (SNP) | VAF 5/37 reads (14%) | catalogued as rs756859195, COSV57346815; called by muse, mutect2, varscan2
- COL4A1 | c.878G>A p.G293D | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65432395; called by muse, mutect2
- CTAGE1 | c.446A>T p.E149V | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV66945069; called by muse, mutect2
- CYP4X1 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as COSV64149879; called by muse, mutect2, varscan2
- DGKB | c.2009G>C p.G670A | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51823073, COSV99343744; called by muse, mutect2
- DIS3L2 | c.1106G>T p.S369I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV56053910; called by muse, mutect2, varscan2
- DMD | c.1722G>A p.W574* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99926656; called by muse, mutect2, varscan2
- DNAJC14 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1481142295, COSV57912186, COSV57914103; called by muse, mutect2, varscan2
- DNAJC14 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100423752, COSV57914134; called by muse, mutect2, varscan2
- EPHB1 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.364); catalogued as COSV67672316; called by muse, varscan2
- FAT1 | c.11868C>G p.I3956M | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV71676123; called by muse, varscan2
- FBXO43 | c.1405C>A p.Q469K | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV71055596; called by muse, mutect2
- FGFRL1 | c.1351G>C p.G451R | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.548); catalogued as COSV99294892; called by muse, mutect2
- GLYR1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.135); catalogued as rs369808296, COSV58928875; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPC5 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1275782536, COSV65631266; called by muse, mutect2, varscan2
- GPNMB | c.1382C>T p.S461F (on ENST00000381990 / NM_001005340.2; = p.S449F on NM_002510.3) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV51701196; called by muse, mutect2, varscan2
- GPR152 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.984); catalogued as COSV56888269; called by muse, mutect2
- GSTO2 | c.71T>G p.I24S | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58539829; called by muse, mutect2, varscan2
- HINFP | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63432787; called by muse, mutect2
- IL18RAP | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1182425718, COSV99962453; called by muse, mutect2
- IPO9 | c.3001C>T p.Q1001* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100843583; called by muse, mutect2, varscan2
- KMT2C | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.091); catalogued as COSV51504745; called by muse, mutect2
- KRT16 | c.803G>C p.G268A | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV56969433, COSV56969862; called by muse, mutect2, varscan2
- LDHC | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs760395380, COSV55004394; called by muse, mutect2, varscan2
- LMNB2 | c.1855G>A p.V619M | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as rs748688330, COSV53115385; called by muse, mutect2, varscan2
- MACF1 | c.14439G>T p.W4813C (on ENST00000372915; = p.W2746C on NM_012090.5) | Missense Mutation (SNP) | VAF 16/178 reads (9%) | catalogued as COSV57145372; called by muse, mutect2
- MAP7D2 | c.731C>G p.A244G | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as COSV65530465; called by muse, mutect2, varscan2
- MARCHF10 | c.1654C>G p.Q552E | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.152); catalogued as COSV60890620; called by muse, mutect2, varscan2
- MARCHF6 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV56887346; called by muse, mutect2, varscan2
- MDN1 | c.7055G>T p.R2352L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV65518993, COSV65530738; called by mutect2, varscan2
- MRPL37 | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs200125721, COSV60322853; called by muse, mutect2, varscan2
- NHS | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | catalogued as COSV101197030; called by muse, mutect2, varscan2
- NINL | c.3952G>A p.E1318K | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.871); catalogued as COSV54009311; called by muse, mutect2, varscan2
- OCLN | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201347125, COSV62286086; called by muse, mutect2
- OR10A6 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs148940548, COSV59165179; called by muse, mutect2, varscan2
- PCDHA6 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65358177; called by muse, mutect2
- PCNX1 | c.5446G>C p.E1816Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99457414; called by muse, mutect2
- PDE5A | c.449C>G p.S150* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as COSV53355038, COSV99309290; called by muse, mutect2, varscan2
- PLCG1 | c.417G>A p.W139* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99719342; called by muse, mutect2
- PTPN2 | c.705G>C p.L235F | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58999334; called by muse, mutect2
- PTTG1IP | c.507A>T p.K169N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV58367036; called by muse, mutect2, varscan2
- PXN | c.1466C>T p.S489L (on ENST00000228307 / NM_001080855.3; = p.S455L on NM_002859.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV57222010; called by muse, mutect2
- RANBP2 | c.7292C>T p.S2431L | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.36); catalogued as rs748998622, COSV51700763, COSV99313431; called by muse, mutect2, varscan2
- RAP1GAP | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51578685, COSV99265704; called by muse, mutect2, varscan2
- RBM10 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100237770, COSV61308772, COSV61309636; called by muse, mutect2, varscan2
- RBM15 | c.2658G>T p.R886S | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63924528; called by muse, mutect2, varscan2
- RNF167 | c.1031C>G p.S344C | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV52592191; called by muse, mutect2, varscan2
- RPL23 | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55560669; called by muse, mutect2, varscan2
- RPTOR | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs755927307, COSV60817740; called by mutect2, varscan2
- RSPH4A | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57636876; called by muse, mutect2, varscan2
- RUFY1 | c.804G>C p.L268F | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as COSV60163957; called by muse, mutect2
- RYR1 | c.8541G>A p.Q2847= | Splice Region (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100617122; called by muse, mutect2
- RYR2 | c.11308A>T p.N3770Y | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63715729; called by muse, mutect2, varscan2
- SEMA6B | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs756420377, COSV56706210; called by muse, mutect2, varscan2
- SLC27A2 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV51058194, COSV51058382; called by muse, mutect2
- SLC45A1 | c.2068C>G p.L690V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV57100702; called by muse, mutect2, varscan2
- SPATA22 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs749381768, COSV52154807; called by muse, mutect2, varscan2
- SPSB2 | c.272G>T p.W91L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51290433; called by muse, mutect2
- SPTAN1 | c.2393C>T p.T798M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs749263783, COSV63989959; called by muse, mutect2, varscan2
- TBC1D22A | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61446658; called by muse, mutect2, varscan2
- THNSL1 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs753955093, COSV64479980; called by muse, mutect2
- TMC2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV62652781, COSV62658733; called by muse, mutect2
- TOPBP1 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV53435932, COSV53442116; called by muse, mutect2, varscan2
- U2AF2 | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.764); catalogued as COSV100454029, COSV58276374; called by muse, mutect2, varscan2
- UBA6 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV100451724, COSV59176999, COSV59181160; called by muse, mutect2, varscan2
- UBE3C | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as COSV61955748; called by muse, varscan2
- ZNF420 | c.1230G>C p.Q410H | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV58493918; called by muse, mutect2, varscan2
- ZNF578 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV69737524; called by muse, mutect2, varscan2
- ZNF614 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV54548343; called by muse, mutect2, varscan2
- ZNF761 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV61889544; called by muse, mutect2, varscan2
- ZNF777 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as COSV56100450; called by muse, mutect2, varscan2
- ZNF99 | c.2119T>C p.C707R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68056864; called by muse, mutect2, varscan2
- ZP2 | c.1586G>C p.R529T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.06); catalogued as rs370008514; called by muse, mutect2
- DEPDC5 | c.146+2_146+15del p.X49_splice | Splice Site (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- IPP | c.1567_1611del p.R523_V537del | In Frame Del (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel
- NCOR1 | c.4051_4052insAACA p.I1351Kfs*4 | Frame Shift Ins (INS) | VAF 29/117 reads (25%) | called by mutect2, pindel, varscan2
- THSD4 | c.2079_2080del p.L694Gfs*32 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- TP53 | c.1129_1132del p.T377Pfs*44 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel
- ZNF26 | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- AARS2 | c.573G>A p.L191= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV55117675; called by muse, mutect2, varscan2
- ABLIM2 | c.1698A>G p.K566= (on ENST00000341937 / NM_001130084.2; = p.K476= on NM_032432.5) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99590634; called by muse, mutect2
- ADRA1A | c.126G>A p.L42= | Silent (SNP) | VAF 31/244 reads (13%) | catalogued as COSV52374780; called by muse, mutect2, varscan2
- AUP1 | c.1179A>G p.L393= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs377410884; called by muse, mutect2, varscan2
- CFL1 | c.105G>A p.A35= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs762181259, COSV57382140; called by muse, mutect2, varscan2
- DNAH1 | c.2130C>T p.I710= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV70236693; called by muse, mutect2, varscan2
- GPR19 | c.253C>T p.L85= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV60124779; called by muse, mutect2, varscan2
- ITPR1 | c.5526C>T p.S1842= (on ENST00000354582; = p.S1787= on NM_002222.7) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV57005179; called by muse, mutect2, varscan2
- KCNC3 | c.1356C>T p.I452= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs147215054; called by muse, mutect2, varscan2
- MGAM | c.3678C>G p.T1226= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV72075919; called by muse, mutect2, varscan2
- MMP9 | c.1098C>T p.R366= | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as COSV63434527; called by muse, mutect2
- MROH5 | c.117A>G p.S39= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV71302959; called by muse, mutect2
- OR52A1 | c.870C>G p.L290= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV61093372; called by muse, varscan2
- OR52K2 | c.606C>T p.I202= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as rs569235087, COSV57834566; called by muse, mutect2, varscan2
- OR6K2 | c.489T>C p.S163= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV62744286; called by muse, mutect2
- PCDHA13 | c.2190C>T p.G730= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV56504226, COSV99166229; called by muse, mutect2, varscan2
- PEX12 | c.205C>T p.L69= | Silent (SNP) | VAF 54/190 reads (28%) | catalogued as COSV56779008; called by muse, mutect2, varscan2
- SCN10A | c.1236A>G p.E412= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as COSV71862724; called by muse, mutect2
- SEMA6B | c.312G>A p.L104= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100015203; called by muse, varscan2
- SLC8A3 | c.714C>G p.L238= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV63526900; called by muse, mutect2, varscan2
- TARBP1 | c.3429C>T p.I1143= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV50182985; called by muse, mutect2, varscan2
- TEKT1 | c.525G>A p.L175= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV58625124; called by muse, mutect2, varscan2
- THEG | c.822G>A p.P274= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs768597942, COSV61074526; called by muse, mutect2
- TRAT1 | c.297T>A p.S99= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV55471063; called by muse, mutect2, varscan2
- UBE3C | c.1785G>A p.Q595= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV61955752; called by muse, varscan2
- VPS13B | c.5781A>G p.S1927= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as COSV62157818; called by muse, mutect2, varscan2
- ZNF432 | c.912C>T p.L304= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as rs756414491, COSV55416279, COSV55417689; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826155 C>G | 3'Flank (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- CTBP1 | chr4:1250814 C>T | 5'Flank (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- DENND10P1 | n.753C>T | RNA (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.567G>A | RNA (SNP) | VAF 18/111 reads (16%) | catalogued as rs782635774; called by muse, mutect2, varscan2
